Somatic mutation profile of tumor specimen TCGA-2Z-A9J3-01A (aliquot TCGA-2Z-A9J3-01A-12D-A382-10) from TCGA case TCGA-2Z-A9J3, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 67.4 years (24,626 days).
Specimen TCGA-2Z-A9J3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0147c88-04b6-49fc-9b0c-301ea76a74f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9J3-10A (Blood Derived Normal), aliquot TCGA-2Z-A9J3-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd99607c-a98a-42f8-b56c-b9947d97e31e

The open-access MAF lists 141 somatic variants for this specimen: 110 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 30, Frame Shift Del 12, Nonsense Mutation 5, Splice Site 4, Frame Shift Ins 4, Intron 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG4 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV100266676, COSV56644190; called by muse, mutect2, varscan2
- ACTR1B | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215343972, COSV100008053, COSV56703523; called by muse, mutect2, varscan2
- AGT | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs559327874, COSV100794299; called by muse, mutect2, varscan2
- AKAP9 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 89/402 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100662246; called by muse, mutect2, varscan2
- APBB2 | c.598A>T p.I200F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV99922820; called by muse, mutect2, varscan2
- APCDD1 | c.1230C>A p.C410* | Nonsense Mutation (SNP) | VAF 42/93 reads (45%) | catalogued as COSV100789935; called by muse, mutect2, varscan2
- ARHGAP10 | c.923G>C p.R308T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV100331130; called by muse, mutect2, varscan2
- ATG13 | c.1190T>A p.F397Y (on ENST00000359513 / NM_001346321.1; = p.F360Y on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100365660; called by muse, mutect2, varscan2
- AVIL | c.1454T>A p.F485Y | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99142305; called by muse, mutect2, varscan2
- B3GALNT1 | c.667C>A p.H223N | Missense Mutation (SNP) | VAF 63/101 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV100251984, COSV100252145; called by muse, mutect2, varscan2
- BAZ1B | c.4300C>G p.Q1434E | Missense Mutation (SNP) | VAF 114/152 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100289681; called by muse, mutect2, varscan2
- BCL10 | c.45A>C p.E15D | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100997785; called by muse, mutect2, varscan2
- BMP4 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as COSV99816859; called by muse, mutect2, varscan2
- BOD1L1 | c.7578G>C p.L2526F | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.368); catalogued as COSV99239023; called by muse, mutect2
- BPTF | c.6155C>G p.T2052R | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100074660; called by muse, mutect2, varscan2
- CAT | c.605A>C p.D202A | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99573174; called by muse, mutect2, varscan2
- CCDC57 | c.350A>T p.Q117L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV66433039; called by muse, mutect2
- CD22 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as rs1293917139, COSV99323075; called by muse, mutect2, varscan2
- CNMD | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV100937205; called by muse, mutect2, varscan2
- CST2 | c.247T>A p.Y83N | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100491181, COSV59030303; called by muse, mutect2, varscan2
- DLK2 | c.503del p.G168Vfs*6 | Frame Shift Del (DEL) | VAF 45/118 reads (38%) | catalogued as COSV55089222; called by mutect2, pindel, varscan2
- DMXL2 | c.8263G>T p.A2755S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99196215; called by muse, mutect2, varscan2
- DYRK1A | c.1007T>C p.M336T | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100117725; called by muse, mutect2, varscan2
- EPHA6 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV67570518, COSV67579536; called by muse, mutect2, varscan2
- ETFDH | c.1759G>T p.V587L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV56986864; called by muse, mutect2, varscan2
- EVC | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as COSV99381553; called by muse, mutect2, varscan2
- EXT2 | c.119C>T p.T40I (on ENST00000343631; = p.T73I on NM_000401.3) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.293); catalogued as CD162069, COSV100640573; called by muse, mutect2, varscan2
- FAM20A | c.916T>G p.F306V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV99873287; called by muse, mutect2, varscan2
- FBXW9 | c.565T>A p.L189M (on ENST00000587955; = p.L199M on NM_032301.3) | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV100790326; called by muse, mutect2, varscan2
- GABRP | c.781T>G p.W261G | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99516706; called by muse, mutect2, varscan2
- GBF1 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.428); catalogued as COSV100890430; called by muse, mutect2, varscan2
- GCNT2 | c.713A>C p.N238T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV101097353; called by muse, mutect2, varscan2
- GRIN2D | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.503); catalogued as COSV99616273; called by muse, mutect2, varscan2
- HSD17B14 | c.743dup p.A249Cfs*55 | Frame Shift Ins (INS) | VAF 48/130 reads (37%) | catalogued as rs758181057; called by mutect2, pindel, varscan2
- HTR3A | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100248384; called by muse, mutect2, varscan2
- IL32 | c.557C>A p.A186E (on ENST00000396890 / NM_001308078.4; = p.A140E on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1289837883, COSV99145476; called by muse, mutect2, varscan2
- ITPK1 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as COSV99968394; called by muse, mutect2, varscan2
- JDP2 | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99966640; called by muse, mutect2, varscan2
- KIF1B | c.1120G>T p.E374* (on ENST00000377086 / NM_001365952.1; = p.E368* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV99823024; called by muse, mutect2, varscan2
- KIF26B | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.005); catalogued as rs924851806, COSV101313828; called by muse, mutect2, varscan2
- LDLRAP1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100974715; called by muse, mutect2, varscan2
- LMO7 | c.3G>T p.M1? (on ENST00000357063; = p.M16I on NM_005358.5) | Translation Start Site (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100442303; called by muse, varscan2
- LMO7 | c.937C>A p.L313M (on ENST00000357063; = p.L328M on NM_005358.5) | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100412912; called by muse, mutect2, varscan2
- LRRC43 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772961895, COSV60290813; called by muse, mutect2, varscan2
- LY75 | c.828C>G p.F276L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.389); catalogued as COSV99716293; called by muse, mutect2, varscan2
- MAP1A | c.1454A>G p.K485R | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100288440; called by muse, mutect2, varscan2
- MBD4 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99959113; called by muse, mutect2, varscan2
- MORC2 | c.1837C>T p.P613S (on ENST00000397641 / NM_001303256.3; = p.P551S on NM_014941.3) | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99309754; called by muse, mutect2, varscan2
- MTFR1 | c.359T>C p.L120S | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs904739266, COSV100050143; called by muse, mutect2, varscan2
- NCOR1 | c.2568A>T p.R856S | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99249197; called by muse, mutect2, varscan2
- NCSTN | c.1819G>C p.G607R | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99667026; called by muse, mutect2, varscan2
- NR2F2 | c.397T>C p.Y133H | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV67683548; called by muse, mutect2, varscan2
- OFD1 | c.2371C>A p.P791T | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV100406851; called by muse, mutect2, varscan2
- OR2J3 | c.428T>G p.F143C | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV101013607; called by muse, mutect2, varscan2
- OR5P2 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV100271293; called by muse, mutect2, varscan2
- PARD3B | c.122del p.X41_splice | Splice Site (DEL) | VAF 24/108 reads (22%) | catalogued as COSV62533644; called by mutect2, pindel, varscan2
- PARP4 | c.2954T>C p.L985P | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101131481; called by muse, mutect2, varscan2
- PCDHA9 | c.2347A>G p.T783A | Missense Mutation (SNP) | VAF 143/173 reads (83%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100969366; called by muse, mutect2, varscan2
- PCDHGC4 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV99339388; called by muse, mutect2, varscan2
- PDPR | c.1105A>G p.M369V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs541394087, COSV99848095; called by muse, mutect2, varscan2
- PEX1 | c.533A>G p.Q178R | Missense Mutation (SNP) | VAF 149/195 reads (76%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1393773660, COSV99952032; called by muse, mutect2, varscan2
- PHKG1 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 60/78 reads (77%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.53); catalogued as COSV99818143; called by muse, mutect2, varscan2
- PNPLA6 | c.2785T>C p.S929P (on ENST00000414982 / NM_001166111.2; = p.S881P on NM_006702.5) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV55384290, COSV99653485; called by muse, mutect2, varscan2
- PPFIBP2 | c.2178G>T p.W726C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752547943, COSV100206385; called by muse, mutect2, varscan2
- PTPN3 | c.2284C>A p.P762T | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as COSV52706118, COSV99355613; called by muse, mutect2, varscan2
- PTPRE | c.210-1G>C p.X70_splice | Splice Site (SNP) | VAF 45/94 reads (48%) | catalogued as COSV99616817, COSV99617542; called by muse, mutect2
- RALGAPA1 | c.4356C>G p.S1452R | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV99354207; called by muse, mutect2, varscan2
- RDH12 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 240/566 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV99961819; called by muse, mutect2, varscan2
- RNF114 | c.488T>A p.F163Y | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99724720; called by muse, mutect2, varscan2
- RNF19B | c.2057G>C p.G686A | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV99331333; called by muse, mutect2
- RPS6KC1 | c.596del p.S199Wfs*6 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as COSV65298233; called by mutect2, pindel, varscan2
- RRP36 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as rs1458618014; called by muse, mutect2, varscan2
- RUFY3 | c.720G>T p.M240I | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as COSV56916428; called by muse, mutect2, varscan2
- SCNN1G | c.780C>A p.C260* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100264093; called by muse, mutect2, varscan2
- SLC43A2 | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV100024864; called by muse, mutect2, varscan2
- SLC4A4 | c.628C>T p.R210W (on ENST00000264485 / NM_001098484.3; = p.R166W on NM_003759.4) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337721443, COSV99139741; called by muse, mutect2, varscan2
- SLIT2 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV56586880, COSV99882828; called by muse, mutect2, varscan2
- SPTA1 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as rs931070390, COSV100934710; called by muse, mutect2, varscan2
- STAB2 | c.797A>G p.E266G | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV101185859; called by muse, mutect2, varscan2
- STX18 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV100086118; called by muse, mutect2, varscan2
- SYNE2 | c.11347-2A>G p.X3783_splice | Splice Site (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100647372; called by muse, mutect2, varscan2
- SYTL2 | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV100314036; called by muse, mutect2, varscan2
- TCF4 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV100610054; called by muse, mutect2, varscan2
- TEP1 | c.5626C>T p.R1876W | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs751753967, COSV99402093; called by muse, mutect2, varscan2
- TGM4 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99942242; called by muse, mutect2, varscan2
- TIAM2 | c.3764A>G p.Y1255C | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99265332; called by muse, mutect2, varscan2
- TTLL5 | c.632T>G p.I211S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99709561; called by muse, mutect2, varscan2
- UNC13A | c.2675G>A p.G892E | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV99407816; called by muse, mutect2, varscan2
- UPP2 | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99134824; called by muse, mutect2, varscan2
- UQCRC2 | c.514+2dup p.X172_splice | Splice Site (INS) | VAF 30/67 reads (45%) | catalogued as rs1567471440; called by mutect2, pindel, varscan2
- WDPCP | c.2097G>C p.R699S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV55412510; called by muse, mutect2, varscan2
- ZNF229 | c.2444A>T p.Q815L | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99350297; called by muse, mutect2, varscan2
- ZNF471 | c.299A>C p.Q100P | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as COSV100340498, COSV100340967; called by muse, mutect2, varscan2
- ZNF517 | c.820T>C p.S274P | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV100743578; called by muse, mutect2, varscan2
- ZNF644 | c.2395A>C p.S799R | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100494384; called by muse, mutect2, varscan2
- DCLRE1B | c.368dup p.Y123* | Nonsense Mutation (INS) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- DDX58 | c.2336del p.K779Rfs*45 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- DSP | c.7131_7132insT p.I2378Yfs*2 | Frame Shift Ins (INS) | VAF 29/68 reads (43%) | called by mutect2, pindel*, varscan2
- ENOSF1 | c.1215del p.F405Lfs*29 (on ENST00000340116 / NM_001354066.2; = p.F371Lfs*29 on NM_017512.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 49/130 reads (38%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.1417del p.D473Ifs*6 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel*, varscan2
- MYH9 | c.1927_1933del p.F643Lfs*13 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- NUP214 | c.4572_4576del p.Q1525Sfs*9 | Frame Shift Del (DEL) | VAF 34/75 reads (45%) | called by mutect2, pindel, varscan2
- OGDHL | c.2878_2887del p.M960* | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- OR5W2 | c.54del p.N19Ifs*5 | Frame Shift Del (DEL) | VAF 31/86 reads (36%) | called by mutect2, pindel, varscan2
- PDS5B | c.3129_3131del p.M1043_V1044delinsI | In Frame Del (DEL) | VAF 120/315 reads (38%) | called by mutect2, pindel, varscan2
- PYROXD2 | c.1511_1512del p.L504Hfs*72 | Frame Shift Del (DEL) | VAF 43/101 reads (43%) | called by mutect2, pindel, varscan2
- RARS1 | c.1805_1806dup p.E603Mfs*27 | Frame Shift Ins (INS) | VAF 28/61 reads (46%) | called by mutect2, varscan2
- SORCS3 | c.3442del p.R1148Gfs*20 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- TTC21A | c.2838_2839insTCCA p.A947Sfs*8 | Frame Shift Ins (INS) | VAF 30/70 reads (43%) | called by mutect2, pindel*, varscan2
- XRN1 | c.711_714del p.C239Lfs*14 | Frame Shift Del (DEL) | VAF 57/342 reads (17%) | called by mutect2, pindel, varscan2
- CD163L1 | c.2853A>G p.G951= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs368493737; called by muse, mutect2, varscan2
- CLIP2 | c.303G>A p.T101= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as rs1554732630, COSV99791348; called by muse, mutect2, varscan2
- DSP | c.60C>T p.A20= | Silent (SNP) | VAF 67/140 reads (48%) | catalogued as COSV101131232; called by muse, mutect2, varscan2
- EIF4B | c.1554T>C p.S518= | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as COSV100016740; called by muse, mutect2, varscan2
- EPHA10 | c.1692C>G p.P564= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV100361191; called by muse, mutect2, varscan2
- FAM71C | c.166A>C p.R56= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV100175720; called by muse, mutect2, varscan2
- GBP3 | c.1777C>T p.L593= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99352452; called by muse, mutect2, varscan2
- GEMIN5 | c.1785A>G p.E595= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as rs1332978253, COSV99593803; called by muse, mutect2, varscan2
- HACD1 | c.423T>A p.T141= | Silent (SNP) | VAF 11/171 reads (6%) | catalogued as COSV100778487; called by muse, mutect2
- KCNA5 | c.63G>A p.E21= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99363811; called by muse, mutect2, varscan2
- KCNJ13 | c.900A>G p.A300= | Silent (SNP) | VAF 63/139 reads (45%) | catalogued as COSV99289292; called by muse, mutect2, varscan2
- LPIN1 | c.1236G>A p.L412= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV99877384; called by muse, mutect2, varscan2
- MDC1 | c.885T>G p.P295= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV100902721; called by muse, mutect2, varscan2
- MERTK | c.741C>T p.S247= | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as rs760912044, COSV99774447; called by muse, mutect2
- MINAR1 | c.2727G>T p.V909= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100548818; called by muse, mutect2
- MRC2 | c.2556C>A p.I852= | Silent (SNP) | VAF 64/106 reads (60%) | catalogued as COSV100316113; called by muse, mutect2, varscan2
- NRXN1 | c.258C>T p.G86= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV101277460; called by muse, mutect2, varscan2
- NUP188 | c.807T>C p.S269= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV101001291; called by muse, mutect2, varscan2
- NYAP2 | c.273T>C p.H91= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs373061629, COSV99078599; called by muse, mutect2, varscan2
- PFN3 | c.150G>A p.V50= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99499579; called by muse, mutect2, varscan2
- PLEKHA4 | c.2028C>A p.L676= | Silent (SNP) | VAF 63/131 reads (48%) | catalogued as COSV99612362; called by muse, mutect2, varscan2
- PPFIA4 | c.1365G>A p.E455= (on ENST00000447715; = p.E451= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV99690475; called by muse, mutect2, varscan2
- SALL1 | c.3867G>A p.E1289= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as COSV99173168; called by muse, mutect2, varscan2
- SCN9A | c.1503G>A p.S501= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs766468627, COSV57598550; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMCO3 | c.84C>T p.C28= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV99660630; called by muse, mutect2, varscan2
- SPTBN5 | c.5349C>G p.G1783= | Silent (SNP) | VAF 49/121 reads (40%) | catalogued as COSV100311145; called by muse, mutect2, varscan2
- STAM2 | c.1290T>G p.S430= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV99812965; called by muse, mutect2, varscan2
- SYT16 | c.639T>G p.S213= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV101413562; called by muse, mutect2, varscan2
- TMEM237 | c.15G>A p.S5= | Silent (SNP) | VAF 65/135 reads (48%) | catalogued as COSV99635777; called by muse, mutect2, varscan2
- UBE2O | c.2856G>A p.K952= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100084420; called by muse, mutect2, varscan2
- PDE4B | c.635-91A>C | Intron (SNP) | VAF 42/86 reads (49%) | catalogued as COSV100303098; called by muse, mutect2, varscan2
